Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A1CV, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A1CV-01A (Primary Tumor).

[page 1 of 3]
ICD -0 -3
Carcinoma, papillary, thyroid 8260/3 1/9/11
Site Code: Thyroid, NOS C73.9
lw

Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender: F

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Parathyroid: Right Lower
2. Thyroid: total thyroid stitch marks upper pole Rt. lobe fresh

Diagnosis

1. No pathological diagnosis: Parathyroid (right lower) biopsy.
2. Multifocal papillary carcinoma, dominant 1.1 cm, left: Thyroid
No pathological diagnosis: Lymph nodes, 3
- Total thyroidectomy specimen

Synoptic Data

Procedure:	Total thyroidectomy
Received:	In formalin
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 6.3 cm 2.7 cm 1.4 cm Left lobe: 5.9 cm 2.9 cm 1.7 cm Isthmus +/- pyramidal lobe: 3.6 cm 1.5 cm 1.0 cm
Specimen Weight:	32.4 g
Tumor Focality:	Multifocal, bilateral
----- DOMINANT TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 1.1 cm Additional dimension: 0.8 cm Additional dimension: 0.8 cm
Histologic Type:	Papillary carcinoma, classical (usual) Classical (papillary) architecture

[page 2 of 3]
Surgical Pathology Consultation Report

Histologic Grade:	Classical cytomorphology
Margins:	G1: Well differentiated
Tumor Capsule:	Margins uninvolved by carcinoma
Tumor Capsular Invasion:	Totally encapsulated
Lymph-Vascular Invasion:	Present, extent minimal
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 0.5cm
Histologic Type:	Papillary carcinoma, follicular variant
	Follicular architecture
	Classical cytomorphology
Histologic Grade:	G1: Well differentiated
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT1: Tumor size 2 cm or less, limited to thyroid
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis
	Number of regional lymph nodes examined: 3
	Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Parathyroid gland(s), within normal limits
	Other: additional bilateral papillary microcarcinomas

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Clinical History

papillary thyroid ca

Gross Description

1. The specimen labeled with the patient's name and as "Parathyroid: Right lower" consists of a piece of tissue that weighs 0.003 g and measures 0.2 x 0.1 x 0.1 cm. It is frozen for intraoperative consultation.

1A frozen section block resubmitted

2. The specimen labeled with the patient's name and as "Thyroid: Total thyroid stitch marks upper pole right lobe fresh" consists of a thyroid gland that is oriented with a stitch and weighs 32.4 g. The right lobe measures 6.3 cm SI x 2.7 cm ML x 1.4 cm AP, the left lobe measures 5.9 cm SI x 2.9 cm ML x 1.7 cm AP and the isthmus measures 3.6 cm SI x 1.5 cm ML x 1.0 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands and lymph nodes are identified grossly. The external surface is painted with Silver nitrate. The left upper lobe contains a well delineated nodule that measures 0.8 cm SI x 0.8 cm ML x 1.1 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Sections of left lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

2A-K right lobe, superior to inferior

isthmus

2C-W left lobe, superior to inferior

[page 3 of 3]
Surgical Pathology Consultation Report

Quick Section Diagnosis

1. Parathyroid tissue confirmed
Time reported to surgeon:

Source: NCI Genomic Data Commons file 2d771fa1-688f-45d7-8414-02248e04386a (TCGA-EM-A1CV.02C9BA4F-692D-4658-ABE4-89C22A0D512F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).